TARGET case TARGET-30-PANLET — Neuroblastoma (TARGET-NBL)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neuroepitheliomatous Neoplasms; Primary site: Adrenal gland. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/15c98cf6-12ac-5a85-81c0-216c6d226b14

Demographics
Sex at birth: female; Age at index: 5 years; Vital status: Dead; Days to death: 1,212 days (3.3 years).

Diagnoses (1)
1. Ganglioneuroblastoma: ICD-O-3 morphology code: 9490/3; ICD-10 code: C74.9; Tissue or organ of origin: Adrenal gland, NOS; Classification of tumor: primary; Age at diagnosis: 5.4 years (1,973 days); Year of diagnosis: 2005; Days to last follow up: 1,212 days (3.3 years); Cog neuroblastoma risk group: High Risk; INSS stage: Stage 4.
   Treatment given: Protocol identifier: ANBL0421.
   Treatment given: Protocol identifier: ANBL00B1.

Follow-up (3 entries)
- Days to follow up: 830 days (2.3 years); Progression or recurrence anatomic site: Bone, NOS; Days to first event: 830 days (2.3 years); First event: Relapse.
- Days to follow up: 830 days (2.3 years); Progression or recurrence anatomic site: Bone marrow.
- Days to follow up: 1,212 days (3.3 years); Year of follow up: 2008.

Molecular and laboratory tests
- MYCN amplification: Not Amplified.
- Test: Normal; Ploidy: Diploid.

Biospecimens (3 samples)
- Samples TARGET-30-PANLET-01A, TARGET-30-PANLET-01B (2 with the same recorded description): Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
- Sample TARGET-30-PANLET-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the TARGET clinical supplement workbook TARGET_NBL_ClinicalData_Discovery_20230523.xlsx (sheet Clinical Data):
- Overall Survival Time in Days: 1212
- Protocol: ANBL00B1, ANBL0421
- Ploidy: Diploid (DI=1)
- Ploidy Value: 1
- Histology: Unfavorable
- Diagnostic Category: Ganglioneuroblastoma, nodular
- ICDO Description: Adrenal gland, NOS Suprarenal gland Adrenal, NOS
- Site of Relapse: Bone; Bone Marrow
